Somatic mutation profile of tumor specimen C3L-02741-01 (aliquot CPT0188190007) from CPTAC case C3L-02741, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 59.6 years (21,785 days).
Specimen C3L-02741-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2814690-3327-4d61-9b1e-2eb9a29a9071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02741-31 (Blood Derived Normal), aliquot CPT0183110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/916f91ae-9bd0-4397-bd8f-85c436e426d0

The open-access MAF lists 102 somatic variants for this specimen: 73 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 22, Nonsense Mutation 6, 3'UTR 3, Intron 3, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 129/577 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ECEL1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs532757890, CM146136, COSV100458474; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 36/316 reads (11%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by pindel, varscan2
- ADGRG4 | c.7633C>T p.R2545C | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs765210618; called by muse, mutect2
- C16orf96 | c.2467G>A p.V823I | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1021766370, COSV101474581; called by muse, mutect2, varscan2
- CACNA1E | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62393312; called by muse, mutect2, varscan2
- COL20A1 | c.3567C>T p.G1189= | Splice Region (SNP) | VAF 78/381 reads (20%) | catalogued as rs746683676, COSV58920067; called by muse, mutect2, varscan2
- COL5A1 | c.4577C>T p.P1526L | Missense Mutation (SNP) | VAF 100/453 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs863223459, COSV100880653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISPLD2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280091250, COSV52280583, COSV99295429; called by muse, mutect2, varscan2
- DNAH5 | c.10229C>T p.T3410M | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs186180802; called by muse, mutect2, varscan2
- DNAJC6 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs1376257471; called by muse, mutect2
- DSCAM | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 52/947 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as rs957826009, COSV68032890; called by muse, mutect2
- ENGASE | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748662225, COSV56133850; called by muse, mutect2, varscan2
- FBRS | c.1031C>T p.P344L (on ENST00000287468; = p.P864L on NM_001105079.3) | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs770049951; called by muse, mutect2
- FGF8 | c.664C>T p.R222C (on ENST00000344255 / NM_033164.4; = p.R204C on NM_006119.6) | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs780335350; called by muse, mutect2, varscan2
- GEM | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs761960990, COSV52599103; called by muse, mutect2
- IQCA1 | c.2133C>T p.Y711= | Splice Region (SNP) | VAF 40/160 reads (25%) | catalogued as rs779686716; called by muse, varscan2
- MASP1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 42/620 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369648641; called by muse, mutect2
- MIS18A | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1209254338, COSV51589604; called by muse, mutect2
- NPC1 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV52584109; called by muse, mutect2
- PLIN5 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs377199527; called by muse, varscan2
- PREPL | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 102/494 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.189); catalogued as COSV53218418; called by muse, mutect2, varscan2
- PTEN | c.228T>A p.Y76* | Nonsense Mutation (SNP) | VAF 162/355 reads (46%) | catalogued as COSV64288768, COSV64307557, COSV64310364; called by muse, mutect2, varscan2
- RILPL1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320960170, COSV61552829; called by muse, mutect2, varscan2
- ROBO4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151234078; called by muse, mutect2
- SAFB | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99412417; called by muse, mutect2
- SERPINC1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as rs201381904, COSV62929109; called by muse, mutect2
- SMG6 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780823712; called by muse, mutect2, varscan2
- TDRD15 | c.3715G>T p.V1239F | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs1353583142; called by muse, mutect2
- TRIM35 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1288201067; called by muse, mutect2
- TRRAP | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62842499; called by muse, mutect2, varscan2
- TTC3 | c.5353G>T p.E1785* | Nonsense Mutation (SNP) | VAF 97/416 reads (23%) | catalogued as rs1326950646; called by muse, mutect2, varscan2
- UBXN2A | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100465268; called by muse, mutect2, varscan2
- WIZ | c.4123G>C p.A1375P (on ENST00000673675 / NM_001371589.1; = p.A280P on NM_021241.3) | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV54605117; called by muse, mutect2, varscan2
- ZC3H6 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs749734280; called by muse, mutect2, varscan2
- ZCCHC12 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs946147207, COSV59570945; called by muse, mutect2, varscan2
- ZDBF2 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148587086; called by muse, mutect2, varscan2
- ZNF438 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as rs773162962, COSV100061032; called by muse, varscan2
- ABCC5 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AOX1 | c.3934A>T p.R1312W | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARSL | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 162/621 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2 | c.3373G>A p.V1125M | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- BBS2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 89/455 reads (20%) | called by muse, mutect2, varscan2
- CIC | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 31/621 reads (5%) | called by muse, mutect2
- COL1A1 | c.3599T>G p.F1200C | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ENG | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); called by muse, mutect2
- GPAT2 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 168/739 reads (23%) | called by muse, mutect2, varscan2
- HDHD5 | c.1052C>T p.S351L (on ENST00000336737 / NM_033070.3; = p.S321L on NM_017829.5) | Missense Mutation (SNP) | VAF 141/643 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS3ST6 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IFFO2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IRS2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.066); called by muse, mutect2
- KRT2 | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LDAH | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- LORICRIN | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MAP3K1 | c.2185del p.I729Lfs*10 | Frame Shift Del (DEL) | VAF 44/287 reads (15%) | called by mutect2, pindel, varscan2
- MGAT4B | c.1385dup p.L463Afs*100 | Frame Shift Ins (INS) | VAF 94/562 reads (17%) | called by mutect2, pindel, varscan2
- MNS1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC12 | c.6475C>G p.Q2159E (on ENST00000379442; = p.Q2016E on NM_001164462.1) | Missense Mutation (SNP) | VAF 146/2768 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2
- MUC17 | c.5660T>A p.L1887H | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- NAIP | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2
- NDFIP2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NHS | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 42/1049 reads (4%) | called by muse, mutect2
- NPC1L1 | c.3583C>T p.L1195F | Missense Mutation (SNP) | VAF 96/515 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNISR | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SIN3A | c.1915_1917del p.K639del | In Frame Del (DEL) | VAF 28/140 reads (20%) | called by pindel, varscan2
- SKOR2 | c.771C>A p.S257R | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.331); called by muse, mutect2
- SMC5 | c.2647A>C p.T883P | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2
- TARS2 | c.1364A>T p.Q455L | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- ZNF175 | c.300G>C p.R100S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF284 | c.410T>G p.L137R | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ABCA1 | c.3582C>A p.A1194= | Silent (SNP) | VAF 27/713 reads (4%) | called by muse, mutect2
- COL6A1 | c.1137C>T p.D379= | Silent (SNP) | VAF 30/524 reads (6%) | catalogued as rs1009125960, COSV62612174, COSV62613991; called by muse, mutect2
- CRNN | c.288C>T p.A96= | Silent (SNP) | VAF 16/338 reads (5%) | called by muse, mutect2
- CSMD3 | c.4650T>C p.V1550= (on ENST00000297405 / NM_001363185.1; = p.V1446= on NM_052900.3) | Silent (SNP) | VAF 82/391 reads (21%) | called by muse, mutect2, varscan2
- DNAH6 | c.1122T>C p.A374= | Silent (SNP) | VAF 17/354 reads (5%) | catalogued as rs1025162423; called by muse, mutect2
- FBXL16 | c.718C>T p.L240= | Silent (SNP) | VAF 54/240 reads (23%) | called by muse, mutect2, varscan2
- FLNC | c.3558G>A p.A1186= | Silent (SNP) | VAF 68/275 reads (25%) | catalogued as rs774467047, COSV57953570; called by muse, mutect2, varscan2
- HUWE1 | c.12942C>T p.L4314= | Silent (SNP) | VAF 65/345 reads (19%) | catalogued as rs782813587, COSV53353975; called by muse, mutect2, varscan2
- IKZF1 | c.342C>T p.N114= | Silent (SNP) | VAF 22/548 reads (4%) | catalogued as rs185632810; called by muse, mutect2
- KCNJ9 | c.447G>A p.V149= | Silent (SNP) | VAF 99/431 reads (23%) | called by muse, mutect2, varscan2
- KMT2D | c.16233C>T p.L5411= | Silent (SNP) | VAF 98/454 reads (22%) | called by muse, mutect2, varscan2
- LRRC25 | c.447C>G p.L149= | Silent (SNP) | VAF 151/685 reads (22%) | called by muse, mutect2, varscan2
- MGAT5B | c.2058G>A p.A686= (on ENST00000569840 / NM_001199172.2; = p.A684= on NM_144677.3) | Silent (SNP) | VAF 99/400 reads (25%) | catalogued as rs374024223; called by muse, mutect2, varscan2
- NRAP | c.3054G>A p.K1018= (on ENST00000359988 / NM_001322945.2; = p.K983= on NM_006175.4) | Silent (SNP) | VAF 104/512 reads (20%) | called by muse, mutect2, varscan2
- PROB1 | c.993G>A p.G331= | Silent (SNP) | VAF 66/230 reads (29%) | called by muse, mutect2, varscan2
- PXDNL | c.369T>G p.S123= | Silent (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.1137G>A p.V379= | Silent (SNP) | VAF 14/468 reads (3%) | called by muse, mutect2
- RREB1 | c.4425C>T p.S1475= | Silent (SNP) | VAF 58/239 reads (24%) | catalogued as rs531724612, COSV58558206, COSV58560315; called by muse, mutect2, varscan2
- SOX11 | c.1008G>A p.S336= | Silent (SNP) | VAF 118/497 reads (24%) | catalogued as COSV58985207; called by muse, mutect2, varscan2
- SPATA31D1 | c.3138C>T p.L1046= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as rs1237647903; called by muse, mutect2
- ST6GALNAC3 | c.69G>T p.L23= | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- TAF3 | c.1158G>A p.T386= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs117733404; called by muse, mutect2, varscan2
- CDK20 | c.*140C>T | 3'UTR (SNP) | VAF 76/337 reads (23%) | catalogued as rs753038570; called by muse, mutect2, varscan2
- CFD | c.*20C>G | 3'UTR (SNP) | VAF 96/448 reads (21%) | called by muse, mutect2, varscan2
- GVINP1 | n.6447C>T | RNA (SNP) | VAF 12/59 reads (20%) | catalogued as rs960666555; called by muse, mutect2, varscan2
- KIAA1328 | c.1523+20587C>T | Intron (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- MTRNR2L1 | c.*6_*8del | 3'UTR (DEL) | VAF 22/127 reads (17%) | catalogued as rs538926233; called by pindel, varscan2
- PISD | c.322-3886G>C | Intron (SNP) | VAF 66/381 reads (17%) | catalogued as COSV56716657; called by muse, mutect2, varscan2
- RPL41 | c.13-18_13-16del | Intron (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
